Somatic mutation profile of tumor specimen MP2PRT-PAPJJD-TMP1-A (aliquot MP2PRT-PAPJJD-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPJJD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,182 days).
Specimen MP2PRT-PAPJJD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8179e4cb-8de6-4f01-ba1b-34155b2a5ded.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJJD-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJJD-NB1-B-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14d80d5c-2c2c-4b7f-8bbc-41188f1cf75c

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 80/284 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/282 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADAMTS1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 195/872 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); catalogued as rs200809949, COSV99536469; called by muse, mutect2, varscan2
- BCAR1 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1362883963, COSV50784879; called by muse, mutect2, varscan2
- CCDC73 | c.214_215del p.L72Sfs*19 | Frame Shift Del (DEL) | VAF 84/261 reads (32%) | catalogued as rs770500366; called by pindel, varscan2
- CHST6 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 191/414 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV60001857; called by muse, mutect2, varscan2
- COL5A3 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 146/319 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145443545; called by muse, mutect2, varscan2
- CPT1C | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 45/448 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs762226784; called by muse, mutect2, varscan2
- FGD3 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 193/414 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs372426495; called by muse, mutect2, varscan2
- HHLA1 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372820713, COSV70153316; called by muse, mutect2
- KDM7A | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1393142770, COSV50094162; called by muse, mutect2, varscan2
- KLHDC4 | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs530763969, COSV99566601; called by muse, mutect2
- MUC12 | c.1418C>T p.S473L (on ENST00000379442; = p.S330L on NM_001164462.1) | Missense Mutation (SNP) | VAF 178/400 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.702); catalogued as rs1295212412; called by muse, mutect2, varscan2
- OR51L1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 172/375 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs745967405, COSV100386353; called by muse, mutect2, varscan2
- PAQR9 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61418094; called by muse, mutect2
- RDH12 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as CM107006; called by muse, mutect2, varscan2
- SSR4 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 57/549 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs782604567; called by muse, mutect2, varscan2
- TAF2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 145/523 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756939412; called by muse, mutect2, varscan2
- TNFRSF8 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 133/331 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs779723451, COSV99821588; called by muse, mutect2, varscan2
- CTCF | c.1059_1060insG p.S354Vfs*55 | Frame Shift Ins (INS) | VAF 138/370 reads (37%) | called by mutect2, pindel, varscan2
- IGKV2-24 | chr2:89176314 TGTACCACTGTGTGAGGAAATTG>CCTCT | Missense Mutation (DEL) | VAF 94/216 reads (44%) | called by pindel, varscan2*
- JAG2 | c.3263G>A p.C1088Y | Missense Mutation (SNP) | VAF 11/363 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- LRRIQ1 | c.2389C>A p.Q797K | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGA | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 143/285 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOCS1 | c.1224G>T p.Q408H | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- COL18A1 | c.3411C>T p.V1137= (on ENST00000359759 / NM_130444.3; = p.V902= on NM_030582.4) | Silent (SNP) | VAF 146/606 reads (24%) | catalogued as rs201512380; called by muse, varscan2
- FAT4 | c.14139G>A p.T4713= | Silent (SNP) | VAF 126/474 reads (27%) | catalogued as rs1336245600; called by muse, mutect2, varscan2
- VGLL2 | c.837G>A p.A279= | Silent (SNP) | VAF 64/674 reads (9%) | called by muse, mutect2
- WDR97 | c.4686C>G p.L1562= | Silent (SNP) | VAF 150/502 reads (30%) | called by muse, varscan2
